Somatic mutation profile of tumor specimen MP2PRT-PAVMSX-TMP1-A (aliquot MP2PRT-PAVMSX-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVMSX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,069 days).
Specimen MP2PRT-PAVMSX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 419a3938-2a79-43aa-b3b7-63ca51d55fac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMSX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMSX-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7830f31c-615b-48d7-acd5-66acebbdcfa7

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 115/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs397507507, CM060445, CM122799, COSV61005734; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASB18 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 189/496 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as rs1241223578, COSV100430929; called by muse, mutect2, varscan2
- CACHD1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200240221, COSV51547290; called by muse, mutect2
- ELAVL2 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 103/409 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV56358129; called by muse, mutect2, varscan2
- MTMR2 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214822130; called by muse, mutect2, varscan2
- ROBO4 | c.2818C>T p.R940W | Missense Mutation (SNP) | VAF 115/413 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs774597376; called by muse, mutect2, varscan2
- SLTM | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 178/446 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs1489471217; called by muse, mutect2, varscan2
- DOT1L | c.929T>G p.V310G | Missense Mutation (SNP) | VAF 140/336 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA4 | c.3945T>G p.S1315R | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHKA1 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 99/442 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNA2 | c.3455G>A p.G1152E | Missense Mutation (SNP) | VAF 199/472 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMC2 | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WWC2 | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 122/485 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AMPH | c.108C>T p.D36= | Silent (SNP) | VAF 65/276 reads (24%) | catalogued as rs770260327; called by muse, mutect2, varscan2
- CCL4 | c.261T>C p.Y87= | Silent (SNP) | VAF 40/372 reads (11%) | called by muse, mutect2, varscan2
- DNAI1 | c.1683C>T p.S561= | Silent (SNP) | VAF 148/493 reads (30%) | catalogued as rs749068442, COSV54284417; called by muse, mutect2, varscan2
- IGKV4-1 | chr2:88886153 ins C | 3'Flank (INS) | VAF 46/119 reads (39%) | called by pindel, varscan2*
